Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V3, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V3-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diaagnosis & History:

year old with FNA left thyroid nodule positive papillary thyroid carcinoma.

Specimens Submitted:

- 1: Delphian lymph node
- 2: Total thyroidectomy and central compartment lymph nodes

DIAGNOSIS:

1. Delphian lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

2. Total thyroidectomy and central compartment lymph nodes:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Psammoma bodies

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.4 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

5-2-12
RD

[page 2 of 3]
Free of tumor

Tumor Multicentricity:
Not identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:
Two unremarkable parathyroid glands

Lymph Nodes:
Fourteen benign lymph nodes

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Delphian lymph node" and consists of a single firm lymph node measuring 0.6 x 0.4 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

2) The specimen is received fresh, labeled "total thyroidectomy and central compartment lymph nodes" and consists of a thyroid weighing 15.5 g. The right lobe measures 4.0 x 1.8 x 1.3 cm, the left lobe measures 4.6 x 2.4 x 1.8 cm and the isthmus measures 1.2 x 1.0 x 0.2 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals three nodules in the left lobe. A 2.4 x 1.8 x 1.6 cm yellow tan partially calcified nodule-left lower lobe, a 1.1 x 0.9 x 0.7 cm tan red homogeneous nodule-left mid lobe, and a third red tan homogeneous nodule measuring 1.1 x 0.8 x 0.6 cm-left upper pole. A central portion of the largest nodule is submitted for . The left thyroid lobe is a sequentially from superior to inferior in its entirety. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen. Submitted for and a photograph has been taken. The remaining tissue is serially sectioned and submitted.

Summary of sections:
N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Delphian lymph node

Block	Sect. Site	PCs
1	LN	1

Part 2: Total thyroidectomy and central compartment lymph nodes

Block	Sect. Site	PCs
1	IS	1
8	LL	8
2	LN	2

[page 3 of 3]
3
2

LT
RL

3
2

Source: NCI Genomic Data Commons file a5b04ac3-d454-4b46-ae81-5e1f5b88f812 (TCGA-DJ-A3V3.1DA78954-60CB-4A8D-9943-02417D2ECF9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).